Somatic mutation profile of tumor specimen HCM-CSHL-0082-C25-01A (aliquot HCM-CSHL-0082-C25-01A-11D-A77E-36) from HCMI case HCM-CSHL-0082-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 77.7 years (28,367 days).
Specimen HCM-CSHL-0082-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae1c00b7-e906-400c-b8bb-7113d8846280.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0082-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0082-C25-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4512de43-1852-4855-9472-bc71d122ab06

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Splice Site 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C2orf50 | c.257+1G>A p.X86_splice | Splice Site (SNP) | VAF 8/216 reads (4%) | catalogued as rs1199046885, COSV101059474; called by muse, mutect2
- MYH1 | c.3418C>T p.R1140C | Missense Mutation (SNP) | VAF 20/416 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1432611647, COSV56848015; called by muse, mutect2
- SEMA5A | c.1903G>A p.V635M | Missense Mutation (SNP) | VAF 8/248 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66795171; called by muse, mutect2
- SLC25A12 | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 14/306 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV55535729; called by muse, mutect2
- ADGRG4 | c.4872G>T p.M1624I | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- DNMT1 | c.3700C>T p.R1234C | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MTMR3 | c.2554G>A p.D852N | Missense Mutation (SNP) | VAF 16/442 reads (4%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2
- STRA8 | c.333A>T p.K111N (on ENST00000275764; = p.K89N on NM_182489.2) | Missense Mutation (SNP) | VAF 12/197 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- USE1 | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 14/338 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.111); called by muse, mutect2
- DTX1 | c.579C>T p.G193= | Silent (SNP) | VAF 7/159 reads (4%) | called by muse, mutect2
